Somatic mutation profile of tumor specimen MMRF_1433_1_BM_CD138pos (aliquot MMRF_1433_1_BM_CD138pos_T1_KAS5U_L01377) from MMRF case MMRF_1433, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.8 years (20,373 days).
Specimen MMRF_1433_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da212ec9-8f49-4b3e-ace8-25ecb24fd642.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1433_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1433_1_PB_Whole_C2_KAS5U_L01389; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/226c500e-22de-4617-b91e-24febccb681f

The open-access MAF lists 107 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 26, Silent 16, Intron 10, 5'UTR 6, Frame Shift Del 5, 5'Flank 4, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.779); catalogued as COSV67016767; called by muse, mutect2, varscan2
- IGLV3-9 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1187894997; called by muse, varscan2
- KLHL29 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1349173171; called by muse, mutect2, varscan2
- NFE2L3 | c.1861_1862del p.K621Efs*7 | Frame Shift Del (DEL) | VAF 46/103 reads (45%) | catalogued as rs777869574, COSV50227502; called by mutect2, pindel, varscan2
- OBSCN | c.3814G>T p.A1272S | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.644); catalogued as COSV52816512; called by muse, mutect2, varscan2
- PRKD2 | c.1903T>A p.L635M | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99354464; called by muse, mutect2, varscan2
- SEPTIN9 | c.292C>T p.P98S (on ENST00000427177 / NM_001113491.2; = p.P80S on NM_006640.4) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs866528394, COSV61202801; called by muse, mutect2, varscan2
- SLC43A2 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100025245; called by muse, mutect2
- WWOX | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs770001837; called by muse, mutect2, varscan2
- ABCC9 | c.3614A>G p.N1205S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ADAM15 | c.143T>G p.V48G | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ADAMTS14 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.247); called by muse, mutect2
- ADAMTS3 | c.1856A>C p.Q619P | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ADRA1A | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- AGL | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARVCF | c.579del p.E194Sfs*128 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- BRINP2 | c.1954T>A p.S652T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC40 | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CHMP1B | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CLVS2 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CREBRF | c.1006A>G p.N336D | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- DIS3 | c.784A>C p.T262P | Missense Mutation (SNP) | VAF 53/55 reads (96%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2
- EHBP1 | c.1147_1151delinsG p.N383Gfs*2 | Frame Shift Del (DEL) | VAF 54/114 reads (47%) | called by pindel, varscan2*
- FAM111B | c.1979A>T p.K660I | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- FAT1 | c.7145A>C p.D2382A | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FREM3 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- HABP2 | c.1432A>C p.N478H | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF4B | c.2383C>T p.L795F | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KRT84 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.435); called by muse, mutect2
- KRT85 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MSR1 | c.643T>A p.L215I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NLGN1 | c.1762A>C p.I588L | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PEX11A | c.372_375del p.H125Tfs*8 | Frame Shift Del (DEL) | VAF 86/202 reads (43%) | called by mutect2, pindel, varscan2
- PTPN23 | c.4837G>A p.G1613R | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PTPRK | c.3020G>C p.G1007A (on ENST00000368215 / NM_001291984.2; = p.G1008A on NM_002844.4) | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- RICTOR | c.2350C>T p.L784F | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SEC62 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SMARCA4 | c.3596T>C p.V1199A | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- TMEM121 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMIGD3 | c.529G>A p.G177R (on ENST00000369717 / NM_001081976.2; = p.G258R on NM_020683.7) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUBD1 | c.376del p.E126Kfs*14 | Frame Shift Del (DEL) | VAF 66/163 reads (40%) | called by mutect2, pindel, varscan2
- ZNF383 | c.1119G>T p.K373N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHRS4 | c.33C>A p.A11= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV57481734; called by muse, mutect2, varscan2
- EMB | c.117G>A p.S39= | Silent (SNP) | VAF 33/281 reads (12%) | catalogued as rs112602380, COSV57482377; called by muse, mutect2, varscan2
- FLNA | c.4059C>T p.C1353= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs1557177531; called by muse, mutect2
- GRIN3B | c.1785C>T p.Y595= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as rs770764248, COSV52260939; called by muse, mutect2, varscan2
- IGLV3-9 | c.126G>C p.G42= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs568866334; called by muse, varscan2
- LCOR | c.381T>G p.G127= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- LIMD2 | c.18A>C p.G6= | Silent (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- NECTIN3 | c.117G>A p.L39= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as rs1452881807; called by muse, mutect2, varscan2
- PIF1 | c.417G>A p.L139= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2
- POC1B-GALNT4 | c.60G>A p.A20= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- RUNDC1 | c.1620C>T p.A540= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs1181271231; called by muse, mutect2
- SLC7A9 | c.105C>T p.G35= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- SOX5 | c.975T>C p.A325= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- TLR7 | c.2337T>C p.L779= | Silent (SNP) | VAF 77/81 reads (95%) | called by muse, mutect2, varscan2
- YEATS2 | c.2088A>G p.G696= | Silent (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- ZNF503 | c.1923G>A p.S641= | Silent (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- ACTG1 | c.-134G>T | 5'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- ADRA2A | c.-305A>G | 5'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- BASP1 | c.*857dup | 3'UTR (INS) | VAF 11/46 reads (24%) | catalogued as rs1168433124; called by mutect2, varscan2*
- CHRM3 | c.*212C>T | 3'UTR (SNP) | VAF 18/63 reads (29%) | catalogued as rs1269912531, COSV55093271; called by muse, mutect2, varscan2
- CROCC | c.*387A>G | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- DDX31 | c.*427A>G | 3'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- DERL1 | c.*1530_*1549dup | 3'UTR (INS) | VAF 12/34 reads (35%) | called by mutect2, pindel
- DIRAS2 | c.*806G>T | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- EML3 | c.22+188C>A | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- EXOC6B | c.1980+2765A>G | Intron (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- FBRS | chr16:30661321 T>A | 5'Flank (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- GMPPA | c.-20-68G>C | Intron (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- GORASP2 | c.*671T>G | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- GPR75 | c.-218C>T | 5'UTR (SNP) | VAF 12/26 reads (46%) | catalogued as rs1317788376; called by muse, mutect2, varscan2
- GVQW3 | c.645-1157C>T | Intron (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2
- HNRNPU | c.634+23C>A | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- INTS3 | c.-54T>G | 5'UTR (SNP) | VAF 29/38 reads (76%) | called by muse, mutect2, varscan2
- LANCL1 | chr2:210433961 C>T | 3'Flank (SNP) | VAF 11/54 reads (20%) | catalogued as rs952231754; called by muse, mutect2, varscan2
- MAGI2 | c.*2101G>A | 3'UTR (SNP) | VAF 25/45 reads (56%) | catalogued as rs1030328624; called by muse, mutect2, varscan2
- MSH6 | chr2:47807434 T>C | 3'Flank (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- MXD3 | c.177-37T>C | Intron (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- OCLN | c.*641G>A | 3'UTR (SNP) | VAF 57/100 reads (57%) | called by muse, mutect2, varscan2
- OSBP | c.*1295C>G | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- OTUD4 | c.*3681C>T | 3'UTR (SNP) | VAF 85/176 reads (48%) | called by muse, mutect2, varscan2
- PI4K2A | c.-27C>G | 5'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2
- PPARGC1B | c.*2918_*2940del | 3'UTR (DEL) | VAF 4/61 reads (7%) | called by mutect2, pindel*
- PRKG1 | c.*3682G>A | 3'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- PSTPIP2 | c.213-65C>A | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- RAB5IF | c.*68A>C | 3'UTR (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2, varscan2
- RFPL4B | c.*628T>A | 3'UTR (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- RFX7 | c.*2364T>C | 3'UTR (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- RPL24 | chr3:101686827 G>A | 5'Flank (SNP) | VAF 4/56 reads (7%) | catalogued as rs1051068409; called by muse, mutect2
- RPL24 | chr3:101686828 C>T | 5'Flank (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- SERINC2 | chr1:31410402 G>A | 5'Flank (SNP) | VAF 7/26 reads (27%) | catalogued as rs540475475; called by muse, mutect2, varscan2
- SESN3 | c.*3556C>G | 3'UTR (SNP) | VAF 6/117 reads (5%) | called by muse, mutect2
- SLC19A1 | c.*1016G>A | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SLC45A4 | c.*3750C>G | 3'UTR (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
- SLC5A10 | c.847-98T>C | Intron (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.*318C>T | 3'UTR (SNP) | VAF 7/62 reads (11%) | catalogued as rs926588686; called by muse, mutect2
- SNTB2 | c.*6916A>T | 3'UTR (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- SNU13 | c.*18C>T | 3'UTR (SNP) | VAF 11/19 reads (58%) | catalogued as rs369403795; called by muse, mutect2, varscan2
- SNX13 | c.*363G>T | 3'UTR (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- SNX3 | c.*684T>G | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- THUMPD2 | c.672+540C>T | Intron (SNP) | VAF 34/68 reads (50%) | catalogued as rs1396965157; called by muse, mutect2, varscan2
- TMEM144 | c.109+550T>C | Intron (SNP) | VAF 42/75 reads (56%) | called by muse, mutect2, varscan2
- WDR33 | c.*1261T>G | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2
- WDR86 | c.-226G>A | 5'UTR (SNP) | VAF 14/30 reads (47%) | catalogued as rs949454830; called by mutect2, varscan2
- XRN1 | c.*3680C>T | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- ZPLD1 | chr3:102478266 T>C | 3'Flank (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
